Somatic mutation profile of tumor specimen HTMCP-03-06-02410-01A (aliquot HTMCP-03-06-02410-01A-01D-10409) from CGCI case HTMCP-03-06-02410, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.9 years (21,142 days).
Specimen HTMCP-03-06-02410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7edd72a-b85a-4464-bdac-f1aa96adc964.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02410-10A (Blood Derived Normal), aliquot HTMCP-03-06-02410-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82cf0a4e-382b-4196-bcbd-100ddb9383be

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7, Splice Region 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100382558; called by muse, mutect2
- BPI | c.578T>C p.I193T (on ENST00000262865; = p.I189T on NM_001725.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758151931; called by muse, mutect2, varscan2
- FAM47A | c.2314A>G p.I772V | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV60495876; called by muse, mutect2, varscan2
- FAM47A | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753875155, COSV60498289, COSV60499246; called by muse, mutect2, varscan2
- JAKMIP3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753880520; called by muse, mutect2, varscan2
- LAMA2 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs138765295, COSV70349027; called by muse, mutect2, varscan2
- NID1 | c.2440G>T p.D814Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV51629728; called by muse, mutect2, varscan2
- OR2M5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs147580819; called by muse, mutect2, varscan2
- PCDHB2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.158); catalogued as COSV99522789, COSV99523365; called by muse, mutect2, varscan2
- PRDM9 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV57010121; called by muse, mutect2, varscan2
- RFC4 | c.132-6C>T | Splice Region (SNP) | VAF 8/102 reads (8%) | catalogued as rs749560125, COSV56216498; called by muse, mutect2
- TCF20 | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs140164790; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1420_1422del p.K474del | In Frame Del (DEL) | VAF 13/98 reads (13%) | catalogued as rs1411607461; called by mutect2, pindel, varscan2
- AHCTF1 | c.1554A>T p.L518F (on ENST00000366508; = p.L492F on NM_015446.5) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.4617C>G p.F1539L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBFB | c.165+2dup p.X55_splice | Splice Site (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- CHD1 | c.4981C>T p.H1661Y | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CNST | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH14 | c.738G>T p.E246D (on ENST00000445597; = p.E69D on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- HUWE1 | c.12029A>C p.E4010A | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ITIH2 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); called by muse, mutect2
- LRRD1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAG1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RBM10 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TDRD6 | c.3335T>C p.V1112A | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPA1 | c.2077A>G p.N693D | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- UTP20 | c.4489C>G p.L1497V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP31 | c.1146C>A p.S382= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- HFM1 | c.3105C>T p.D1035= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as rs748543481, COSV54036743, COSV99646149; called by mutect2, varscan2
- KIR3DL3 | c.543C>T p.S181= | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as rs1379903800, COSV99399810; called by muse, mutect2, varscan2
- PCDHB15 | c.1377C>T p.F459= | Silent (SNP) | VAF 53/386 reads (14%) | catalogued as rs782453925, COSV99178826; called by muse, mutect2, varscan2
- PTPRC | c.633C>T p.S211= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs772410895; called by muse, mutect2
- TTN | c.46692G>A p.L15564= (on ENST00000591111; = p.L8140= on NM_003319.4) | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as COSV100593359; called by muse, mutect2, varscan2
- TTN | c.8070C>T p.T2690= (on ENST00000591111; = p.T2644= on NM_003319.4) | Silent (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
